Gene-level copy-number profile of tumor specimen TARGET-20-PARYFN-09A from TARGET case TARGET-20-PARYFN, project TARGET-AML (Acute Myeloid Leukemia). Sex at birth: female; Vital status: Alive; Primary diagnosis: Acute myeloid leukemia, NOS; Tissue or organ of origin: Bone marrow; Age at diagnosis: 4.4 years (1,597 days).
Specimen TARGET-20-PARYFN-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TARGET-AML.ca2d2163-0129-5ce6-b807-20972bc3147c.gene_level_copy_number.v36.tsv, workflow ASCAT2 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TARGET-20-PARYFN-14A (bone marrow normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 349 have no estimate.
https://portal.gdc.cancer.gov/files/13595997-86e3-496c-9b7d-0aacc1f0348d

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 520; copy number 1: 3; copy number 2: 59,588; copy number 3: 163.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): none.

Autosomal genes at a single copy (total copy number 1): 3. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
